Somatic mutation profile of tumor specimen TCGA-CV-6952-01A (aliquot TCGA-CV-6952-01A-11D-1912-08) from TCGA case TCGA-CV-6952, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G1; Age at diagnosis: 65.4 years (23,892 days).
Specimen TCGA-CV-6952-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 99ac851f-b1e7-4e93-bf87-8bcd5f5fc835.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-6952-10A (Blood Derived Normal), aliquot TCGA-CV-6952-10A-01D-1912-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e56a4db1-b585-4614-a28f-7885678c5ee2

The open-access MAF lists 188 somatic variants for this specimen: 141 protein-altering or splice-affecting, 43 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 114, Silent 43, Nonsense Mutation 15, Frame Shift Ins 5, Frame Shift Del 4, 3'UTR 2, 5'Flank 2, In Frame Del 1, Splice Site 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CLPB | c.1249C>T p.R417* | Nonsense Mutation (SNP) | VAF 10/71 reads (14%) | catalogued as rs200203460, CM1412978, COSV53629443; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 12/77 reads (16%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACVR1B | c.1193T>G p.F398C | Missense Mutation (SNP) | VAF 36/123 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57776919; called by muse, mutect2, varscan2
- AKAP12 | c.2717T>C p.I906T | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as rs776331528, COSV53570351; called by muse, mutect2, varscan2
- AMHR2 | c.1216C>T p.R406* | Nonsense Mutation (SNP) | VAF 16/65 reads (25%) | catalogued as rs769617823, COSV57684803, COSV57685504; called by muse, mutect2, varscan2
- ANKRD17 | c.2236C>G p.R746G | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); catalogued as COSV58219434; called by muse, mutect2, varscan2
- ART3 | c.1051C>T p.P351S (on ENST00000355810 / NM_001377173.1; = p.P340S on NM_001179.6) | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.782); catalogued as COSV53575378; called by muse, mutect2
- ASB1 | c.314A>G p.D105G | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV52826836; called by muse, mutect2, varscan2
- BAHCC1 | c.1795G>A p.E599K | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100311191; called by muse, mutect2, varscan2
- BCAR1 | c.2608G>A p.A870T | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.94); catalogued as rs139167479; called by muse, mutect2
- BTAF1 | c.1687A>T p.M563L | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV56433403; called by muse, mutect2, varscan2
- BTN1A1 | c.1325C>G p.S442C | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.538); catalogued as COSV99764186; called by muse, mutect2, varscan2
- C2CD3 | c.3446G>A p.G1149E | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.065); catalogued as rs768568536, COSV58092779; called by muse, mutect2, varscan2
- C4orf33 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55415345; called by muse, mutect2, varscan2
- C5orf24 | c.214A>G p.I72V | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.003); catalogued as rs770775481, COSV57542795; called by muse, mutect2, varscan2
- CCNE2 | c.1088A>G p.Y363C | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.99); catalogued as COSV57375892; called by muse, mutect2, varscan2
- CHD1L | c.902T>G p.F301C | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV63612777; called by muse, mutect2, varscan2
- CHORDC1 | c.403C>G p.L135V | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.074); catalogued as COSV57705936; called by muse, mutect2, varscan2
- COA7 | c.175A>G p.K59E | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.368); catalogued as COSV65299454; called by muse, mutect2, varscan2
- CSMD3 | c.179G>A p.G60E | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.622); catalogued as rs780657908, COSV99825559; called by muse, mutect2, varscan2
- CTTN | c.485A>G p.Y162C | Missense Mutation (SNP) | VAF 29/132 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1327340415, COSV57232041; called by muse, mutect2, varscan2
- CYLC2 | c.557A>G p.K186R | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.593); catalogued as COSV66337387; called by muse, mutect2
- DGKH | c.2737A>G p.I913V | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.576); catalogued as rs772937446, COSV54931466; called by muse, mutect2, varscan2
- DLG5 | c.4012C>T p.R1338W | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs199899533, COSV100967267; called by muse, mutect2, varscan2
- DNAI3 | c.245C>A p.A82D | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV54000626; called by muse, mutect2, varscan2
- DNAJB7 | c.509C>G p.S170C | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.206); catalogued as COSV99343984; called by muse, mutect2, varscan2
- EMP3 | c.124G>A p.D42N | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.6); PolyPhen benign (0.075); catalogued as rs370992861; called by muse, mutect2, varscan2
- EPB41L3 | c.2476A>G p.M826V | Missense Mutation (SNP) | VAF 37/128 reads (29%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs1349274052, COSV100548211; called by muse, mutect2, varscan2
- ERVFRD-1 | c.544C>T p.Q182* | Nonsense Mutation (SNP) | VAF 61/248 reads (25%) | catalogued as rs1420160672, COSV65368939; called by muse, mutect2, varscan2
- FAM47C | c.739C>T p.R247C | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs782690396, COSV63726245; called by muse, mutect2, varscan2
- FAT1 | c.10677C>G p.Y3559* | Nonsense Mutation (SNP) | VAF 15/41 reads (37%) | catalogued as COSV71673532; called by muse, mutect2, varscan2
- FNDC3B | c.2611G>C p.E871Q | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.103); catalogued as COSV100393633; called by muse, mutect2, varscan2
- FOXI1 | c.802C>T p.P268S | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs1258147517, COSV100089073; called by muse, mutect2, varscan2
- FRAS1 | c.10999C>G p.Q3667E | Missense Mutation (SNP) | VAF 45/165 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV53607154, COSV99354699; called by muse, mutect2, varscan2
- GPR174 | c.525G>C p.R175S | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.261); catalogued as COSV52132338; called by muse, mutect2, varscan2
- GRIN3A | c.1545G>C p.L515F | Missense Mutation (SNP) | VAF 27/173 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.377); catalogued as COSV62453142; called by muse, mutect2, varscan2
- GRM1 | c.2591A>G p.K864R | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.551); catalogued as rs1193076599, COSV51138661; called by muse, mutect2, varscan2
- HCFC1 | c.784A>G p.T262A | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.812); catalogued as COSV100128463; called by muse, mutect2
- HDAC6 | c.619A>T p.M207L | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.42); PolyPhen benign (0.037); catalogued as COSV61927519; called by muse, mutect2, varscan2
- HDX | c.330A>G p.I110M | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.305); catalogued as rs766645422, COSV52973087; called by muse, mutect2, varscan2
- HEPH | c.251A>T p.D84V (on ENST00000343002; = p.D138V on NM_138737.5) | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.219); catalogued as COSV57963001; called by muse, mutect2, varscan2
- HNRNPL | c.640A>G p.I214V | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.97); catalogued as COSV99670004; called by muse, mutect2, varscan2
- IFTAP | c.179C>T p.S60L | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.57); PolyPhen benign (0.161); catalogued as COSV57557494; called by muse, mutect2, varscan2
- IKZF5 | c.92G>C p.G31A | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.996); catalogued as COSV100924728; called by muse, mutect2, varscan2
- IL13RA2 | c.1123G>A p.E375K | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.08); catalogued as COSV54563961; called by muse, mutect2, varscan2
- INPP5D | c.113G>A p.R38Q | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.608); catalogued as rs1455184422, COSV64037125; called by muse, mutect2, varscan2
- IRAK3 | c.1286G>A p.R429Q | Missense Mutation (SNP) | VAF 37/137 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.162); catalogued as rs140671957, COSV54166513; called by muse, mutect2, varscan2
- ITLN1 | c.512C>A p.T171K | Missense Mutation (SNP) | VAF 32/133 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370631307, COSV58273846; called by muse, mutect2, varscan2
- JADE2 | c.544A>G p.M182V | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.258); catalogued as COSV99252778; called by muse, mutect2, varscan2
- KIAA1549 | c.1423G>C p.E475Q | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.769); catalogued as COSV54312827; called by muse, mutect2, varscan2
- KIF9 | c.1661T>C p.I554T | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV99646384; called by muse, mutect2, varscan2
- KNL1 | c.6817G>A p.A2273T (on ENST00000346991 / NM_170589.5; = p.A2247T on NM_144508.5) | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.938); catalogued as rs761149870, COSV61154176; called by muse, mutect2, varscan2
- LRATD2 | c.328G>T p.E110* | Nonsense Mutation (SNP) | VAF 25/50 reads (50%) | catalogued as COSV100513525; called by muse, mutect2, varscan2
- LRIG2 | c.2326C>T p.R776C | Missense Mutation (SNP) | VAF 25/136 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as rs755233335, COSV100743001; called by muse, mutect2, varscan2
- LRP1B | c.12445G>T p.E4149* | Nonsense Mutation (SNP) | VAF 21/79 reads (27%) | catalogued as COSV67187412; called by muse, mutect2, varscan2
- MARK1 | c.931A>T p.M311L | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.221); catalogued as COSV65067292; called by muse, mutect2
- MCF2 | c.1717A>T p.R573* | Nonsense Mutation (SNP) | VAF 8/24 reads (33%) | catalogued as COSV58483946; called by muse, varscan2
- MYO16 | c.2791C>G p.L931V | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0.095); catalogued as COSV99193550; called by muse, mutect2, varscan2
- NAV2 | c.7232C>T p.P2411L (on ENST00000396087 / NM_001244963.2; = p.P2352L on NM_145117.5) | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.581); catalogued as rs1484884408, COSV100216177; called by muse, mutect2, varscan2
- NLGN4X | c.384T>G p.F128L | Missense Mutation (SNP) | VAF 25/122 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.074); catalogued as COSV52015800; called by muse, mutect2, varscan2
- NLRP14 | c.1121C>A p.A374D | Missense Mutation (SNP) | VAF 39/157 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV100204586; called by muse, mutect2, varscan2
- NLRP4 | c.2656C>T p.R886W | Missense Mutation (SNP) | VAF 40/163 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.606); catalogued as rs147716168; called by muse, mutect2, varscan2
- NUF2 | c.1327G>T p.D443Y | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.121); catalogued as rs769329199, COSV54843706; called by muse, mutect2, varscan2
- NUP205 | c.1972G>C p.E658Q | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.989); catalogued as COSV53658443; called by muse, mutect2, varscan2
- OFD1 | c.998A>G p.Q333R | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.131); catalogued as COSV60795650; called by muse, mutect2, varscan2
- OR11L1 | c.848C>A p.P283Q | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63314269; called by muse, mutect2, varscan2
- OR11L1 | c.847C>A p.P283T | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1210355427, COSV63314278; called by muse, mutect2, varscan2
- OR2M5 | c.701G>A p.R234H | Missense Mutation (SNP) | VAF 78/266 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs147580819; called by muse, mutect2, varscan2
- OR52A1 | c.304C>T p.Q102* | Nonsense Mutation (SNP) | VAF 8/30 reads (27%) | catalogued as rs763185059, COSV61092372; called by muse, mutect2, varscan2
- P4HTM | c.995G>A p.G332E | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.898); catalogued as COSV100637512; called by muse, mutect2, varscan2
- PCLO | c.11749C>A p.Q3917K | Missense Mutation (SNP) | VAF 129/463 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.542); catalogued as COSV61632290; called by muse, mutect2, varscan2
- PCNT | c.8203C>T p.Q2735* | Nonsense Mutation (SNP) | VAF 10/31 reads (32%) | catalogued as COSV100855071; called by muse, mutect2, varscan2
- PDE6C | c.1558G>A p.G520R | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.107); catalogued as rs267602621, COSV65115012; called by muse, mutect2, varscan2
- PEG3 | c.3916A>C p.N1306H | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.188); catalogued as COSV55625007; called by muse, mutect2, varscan2
- PKDREJ | c.788C>T p.S263F | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.856); catalogued as rs751339091, COSV99478440; called by muse, mutect2
- PKHD1L1 | c.4889G>C p.R1630T | Missense Mutation (SNP) | VAF 72/387 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.153); catalogued as COSV65742154; called by muse, mutect2, varscan2
- PLEKHG7 | c.412C>T p.Q138* | Nonsense Mutation (SNP) | VAF 13/63 reads (21%) | catalogued as COSV101188829; called by muse, mutect2, varscan2
- PRDX4 | c.602G>A p.G201D | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV65025843; called by muse, mutect2, varscan2
- PRKAR2B | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV55924478, COSV55929194; called by muse, mutect2, varscan2
- PTPN21 | c.2105C>G p.S702W | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100161523; called by muse, varscan2
- RIC8A | c.665T>C p.M222T | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.886); catalogued as COSV100254719; called by muse, mutect2, varscan2
- RIMBP2 | c.1645G>A p.V549M | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.586); catalogued as rs770003929, COSV55476117; called by muse, varscan2
- RIMBP2 | c.527A>G p.Y176C | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV55471119; called by muse, mutect2, varscan2
- RNF220 | c.382G>A p.D128N | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.086); catalogued as COSV62406307; called by muse, mutect2, varscan2
- RNGTT | c.152C>G p.S51* | Nonsense Mutation (SNP) | VAF 16/79 reads (20%) | catalogued as COSV55646222, COSV55656779; called by muse, mutect2, varscan2
- RTN4 | c.2008G>A p.V670I | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as COSV58267036; called by muse, mutect2
- SARDH | c.1051G>T p.D351Y | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100897872; called by muse, mutect2, varscan2
- SASS6 | c.76A>G p.I26V | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54926444; called by muse, mutect2, varscan2
- SBF2 | c.59C>T p.S20L | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.134); catalogued as rs867598712, COSV56291669, COSV99812926; called by muse, mutect2
- SCAF11 | c.2893C>T p.R965W | Missense Mutation (SNP) | VAF 42/189 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs112858085, COSV65474709; called by muse, mutect2, varscan2
- SFMBT2 | c.2029G>A p.G677R | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.028); catalogued as rs1449424116, COSV62805463; called by muse, mutect2, varscan2
- SGPL1 | c.928A>G p.I310V | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.162); catalogued as COSV100940283, COSV64591562; called by muse, mutect2, varscan2
- SHISAL1 | c.469C>T p.R157W | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.157); catalogued as rs1020882637; called by muse, mutect2, varscan2
- SI | c.3500T>A p.L1167* | Nonsense Mutation (SNP) | VAF 31/66 reads (47%) | catalogued as COSV52266337; called by muse, mutect2, varscan2
- SLC6A16 | c.682A>T p.M228L | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as COSV60027821; called by muse, mutect2, varscan2
- SLC9A6 | c.1202del p.L401Rfs*14 | Frame Shift Del (DEL) | VAF 22/87 reads (25%) | catalogued as COSV65788583; called by mutect2, pindel, varscan2
- SLITRK6 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.324); catalogued as COSV68390068; called by muse, mutect2
- SORL1 | c.463G>A p.G155S | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.86); PolyPhen benign (0.022); catalogued as COSV99492904; called by muse, mutect2, varscan2
- SP8 | c.1061G>T p.G354V (on ENST00000361443 / NM_198956.4; = p.G372V on NM_182700.6) | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100815268; called by muse, mutect2, varscan2
- STC1 | c.119-2A>T p.X40_splice | Splice Site (SNP) | VAF 21/57 reads (37%) | catalogued as COSV51687760; called by muse, mutect2, varscan2
- SUGP2 | c.2965C>T p.R989W | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs764314944, COSV58255217; called by muse, mutect2, varscan2
- SV2B | c.2026G>C p.E676Q | Missense Mutation (SNP) | VAF 34/127 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.967); catalogued as COSV57698511; called by muse, mutect2, varscan2
- TAF1 | c.2827T>A p.F943I (on ENST00000373790 / NM_138923.4; = p.F964I on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV99334540; called by muse, mutect2, varscan2
- TANGO6 | c.221G>C p.R74T | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.091); catalogued as COSV55760691, COSV99935705; called by muse, mutect2, varscan2
- TARBP1 | c.1468C>A p.L490I | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.656); catalogued as COSV50183596, COSV99241536; called by muse, mutect2, varscan2
- TBL1X | c.278C>T p.T93M | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as rs1322211695, COSV54279427; called by muse, mutect2, varscan2
- TBX22 | c.910T>C p.F304L | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64785815; called by muse, mutect2, varscan2
- TCEAL7 | c.55A>T p.R19W | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV60125071; called by muse, mutect2
- TENM2 | c.5500A>G p.I1834V (on ENST00000518659 / NM_001122679.2; = p.I1595V on NM_001080428.3) | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs999774958, COSV69128800; called by muse, mutect2, varscan2
- THAP12 | c.1175A>T p.H392L | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV52610437; called by muse, mutect2, varscan2
- TUT7 | c.666G>C p.E222D | Missense Mutation (SNP) | VAF 31/180 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV99462456; called by muse, mutect2, varscan2
- USP19 | c.441C>G p.F147L | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); catalogued as COSV59733064; called by muse, mutect2, varscan2
- USP34 | c.10541T>C p.M3514T | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as rs1010295293, COSV63724935; called by muse, mutect2, varscan2
- USP8 | c.1160C>G p.S387C | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.436); catalogued as rs1566874127, COSV56164044; called by muse, mutect2, varscan2
- VARS1 | c.1487C>T p.T496I | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.653); catalogued as COSV65154654; called by muse, mutect2, varscan2
- VPS16 | c.1682C>T p.A561V | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV100988283; called by muse, mutect2, varscan2
- VPS37B | c.259T>G p.Y87D | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.977); catalogued as COSV57360257; called by muse, mutect2, varscan2
- VSIG1 | c.126C>G p.I42M | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.023); catalogued as COSV54257718; called by muse, mutect2, varscan2
- WIPF2 | c.1197G>C p.K399N | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60272249; called by muse, mutect2, varscan2
- YAE1 | c.13C>T p.Q5* | Nonsense Mutation (SNP) | VAF 17/45 reads (38%) | catalogued as COSV56232904; called by muse, mutect2, varscan2
- ZBTB38 | c.1243A>G p.I415V | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.057); catalogued as COSV58541422; called by muse, mutect2, varscan2
- ZC3H11A | c.2331A>G p.I777M | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.148); catalogued as COSV59746036; called by muse, mutect2, varscan2
- ZFHX4 | c.9002G>A p.G3001E | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.92); catalogued as rs775483953, COSV50732994; called by muse, mutect2, varscan2
- ZFP1 | c.1115G>A p.R372Q | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs776971537, COSV60032590; called by muse, mutect2, varscan2
- ZFP3 | c.44C>T p.S15F | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV59582910; called by muse, mutect2, varscan2
- ZFYVE16 | c.2071A>G p.I691V | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs765199817, COSV62015951; called by muse, mutect2, varscan2
- ZNF222 | c.809C>A p.S270* | Nonsense Mutation (SNP) | VAF 36/139 reads (26%) | catalogued as rs768345477, COSV51826586; called by muse, mutect2, varscan2
- ZNF286A | c.439G>T p.V147F | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.71); PolyPhen benign (0.12); catalogued as COSV67845534; called by muse, mutect2, varscan2
- ZNF345 | c.562G>A p.A188T | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.39); PolyPhen benign (0.031); catalogued as rs764966196, COSV100080168; called by muse, mutect2, varscan2
- ZNF595 | c.1393A>G p.T465A | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as COSV100227448; called by muse, mutect2, varscan2
- ZNF616 | c.437C>A p.S146* | Nonsense Mutation (SNP) | VAF 37/162 reads (23%) | catalogued as COSV57510724; called by muse, mutect2, varscan2
- ABR | c.2126_2128dup p.L709_S710insM (on ENST00000302538 / NM_021962.5; = p.L672_S673insM on NM_001092.5) | In Frame Ins (INS) | VAF 65/141 reads (46%) | called by mutect2, pindel, varscan2
- ARHGAP26 | c.1836del p.K612Nfs*34 | Frame Shift Del (DEL) | VAF 14/92 reads (15%) | called by mutect2, pindel, varscan2
- CXCL9 | c.31_42del p.G11_L14del | In Frame Del (DEL) | VAF 13/105 reads (12%) | called by pindel, varscan2
- FAM24B | c.2dup p.M1? | Frame Shift Ins (INS) | VAF 22/89 reads (25%) | called by mutect2, pindel, varscan2
- KDM7A | c.1359dup p.E454* | Frame Shift Ins (INS) | VAF 9/64 reads (14%) | called by mutect2, pindel
- KMT2A | c.5768dup p.M1923Ifs*12 | Frame Shift Ins (INS) | VAF 19/94 reads (20%) | called by mutect2, pindel, varscan2
- MDGA2 | c.1172del p.K391Sfs*7 (on ENST00000399232 / NM_001113498.2; = p.K93Sfs*7 on NM_182830.4) | Frame Shift Del (DEL) | VAF 20/115 reads (17%) | called by mutect2, pindel, varscan2
- SLC25A12 | c.1592dup p.A532Sfs*9 | Frame Shift Ins (INS) | VAF 14/53 reads (26%) | called by mutect2, pindel, varscan2
- UFSP1 | c.330_332delinsT p.G111Lfs*9 | Frame Shift Del (DEL) | VAF 26/123 reads (21%) | called by pindel, varscan2*
- USP34 | c.4588dup p.C1530Lfs*16 | Frame Shift Ins (INS) | VAF 17/58 reads (29%) | called by mutect2, pindel, varscan2
- ABRACL | c.199C>T p.L67= | Silent (SNP) | VAF 37/147 reads (25%) | catalogued as COSV62771465; called by muse, mutect2, varscan2
- AFF4 | c.3069G>A p.K1023= | Silent (SNP) | VAF 40/132 reads (30%) | catalogued as COSV54793436, COSV54794344; called by muse, mutect2, varscan2
- AHNAK | c.16101A>G p.G5367= | Silent (SNP) | VAF 22/96 reads (23%) | catalogued as rs146188257; called by muse, mutect2, varscan2
- APCS | c.345G>C p.V115= | Silent (SNP) | VAF 12/69 reads (17%) | catalogued as COSV54817971; called by muse, mutect2, varscan2
- CABIN1 | c.54A>G p.E18= | Silent (SNP) | VAF 82/269 reads (30%) | catalogued as COSV99572738; called by muse, mutect2, varscan2
- CHST6 | c.585A>G p.L195= | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as rs138994371; called by muse, mutect2, varscan2
- CLDN11 | c.507C>T p.L169= | Silent (SNP) | VAF 32/170 reads (19%) | catalogued as rs764051667, COSV50355404; called by muse, mutect2, varscan2
- DLGAP2 | c.990G>A p.A330= | Silent (SNP) | VAF 40/117 reads (34%) | catalogued as rs1284127378, COSV101421075; called by muse, mutect2, varscan2
- DSG3 | c.2763C>T p.S921= | Silent (SNP) | VAF 22/92 reads (24%) | catalogued as rs767755521, COSV57125965; called by muse, mutect2, varscan2
- EPC2 | c.1164G>A p.P388= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as rs772460144, COSV51543517; called by muse, mutect2, varscan2
- ERCC3 | c.1326A>G p.E442= | Silent (SNP) | VAF 27/121 reads (22%) | catalogued as COSV53426939; called by muse, mutect2, varscan2
- ERCC6L2 | c.4206C>T p.D1402= | Silent (SNP) | VAF 9/46 reads (20%) | called by muse, mutect2, varscan2
- GFAP | c.162G>A p.L54= | Silent (SNP) | VAF 18/65 reads (28%) | catalogued as COSV53650374; called by muse, mutect2, varscan2
- GRK7 | c.972G>T p.L324= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as COSV53822608; called by muse, mutect2, varscan2
- HIPK1 | c.1677C>T p.F559= | Silent (SNP) | VAF 13/57 reads (23%) | catalogued as COSV61247509; called by muse, mutect2, varscan2
- HOOK1 | c.753A>G p.Q251= | Silent (SNP) | VAF 16/51 reads (31%) | catalogued as rs777330903, COSV100968980; called by muse, mutect2, varscan2
- IGSF1 | c.1618A>C p.R540= | Silent (SNP) | VAF 85/312 reads (27%) | catalogued as COSV100811836; called by muse, mutect2, varscan2
- IGSF3 | c.240C>T p.P80= | Silent (SNP) | VAF 6/51 reads (12%) | catalogued as COSV100604120; called by muse, mutect2, varscan2
- KMT2A | c.8733C>A p.V2911= | Silent (SNP) | VAF 42/163 reads (26%) | catalogued as COSV63285349; called by muse, mutect2, varscan2
- LYSMD4 | c.693C>T p.V231= (on ENST00000409796 / NM_001284417.2; = p.V232= on NM_152449.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 49/198 reads (25%) | catalogued as rs998294243, COSV100230526; called by muse, mutect2, varscan2
- MBTPS1 | c.1665A>G p.L555= | Silent (SNP) | VAF 17/97 reads (18%) | catalogued as COSV100597367; called by muse, mutect2, varscan2
- MTBP | c.993T>C p.S331= | Silent (SNP) | VAF 25/175 reads (14%) | catalogued as COSV100011843; called by muse, mutect2, varscan2
- NAV2 | c.7233C>T p.P2411= (on ENST00000396087 / NM_001244963.2; = p.P2352= on NM_145117.5) | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as COSV100216183; called by muse, mutect2, varscan2
- NDUFB11 | c.285C>T p.V95= | Silent (SNP) | VAF 28/93 reads (30%) | catalogued as COSV52102105; called by muse, mutect2, varscan2
- PGAP1 | c.1488G>C p.L496= | Silent (SNP) | VAF 17/69 reads (25%) | catalogued as COSV61325809; called by muse, mutect2, varscan2
- PHLDB2 | c.3450C>T p.L1150= (on ENST00000393925 / NM_001134439.2; = p.L1107= on NM_145753.2) | Silent (SNP) | VAF 17/98 reads (17%) | catalogued as rs765616385, COSV67310781; called by muse, mutect2, varscan2
- PKDREJ | c.786C>T p.F262= | Silent (SNP) | VAF 10/78 reads (13%) | catalogued as rs781177951, COSV99478446; called by muse, mutect2
- PLEC | c.10608G>A p.V3536= (on ENST00000322810 / NM_201380.4; = p.V3426= on NM_000445.5) | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as COSV59616483; called by muse, mutect2, varscan2
- PSMD1 | c.1173A>G p.E391= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as COSV58078374; called by muse, mutect2, varscan2
- PTK7 | c.120C>T p.S40= | Silent (SNP) | VAF 12/67 reads (18%) | catalogued as COSV57848356; called by muse, mutect2, varscan2
- RAPGEF6 | c.4755G>C p.V1585= | Silent (SNP) | VAF 23/107 reads (21%) | catalogued as COSV99725375; called by muse, mutect2, varscan2
- ROS1 | c.1680C>T p.R560= | Silent (SNP) | VAF 27/115 reads (23%) | catalogued as COSV63854665; called by muse, mutect2, varscan2
- SF3B1 | c.363G>A p.K121= | Silent (SNP) | VAF 25/79 reads (32%) | catalogued as COSV59212955; called by muse, mutect2, varscan2
- SLC24A2 | c.1917C>G p.L639= | Silent (SNP) | VAF 35/258 reads (14%) | catalogued as rs41270119, COSV53863798, COSV53871435; called by muse, mutect2, varscan2
- SLCO6A1 | c.6C>T p.F2= | Silent (SNP) | VAF 35/188 reads (19%) | catalogued as COSV65806064; called by muse, mutect2, varscan2
- SP8 | c.1062C>T p.G354= (on ENST00000361443 / NM_198956.4; = p.G372= on NM_182700.6) | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as rs1278438201, COSV100815267; called by muse, mutect2, varscan2
- TECTA | c.1917C>T p.L639= | Silent (SNP) | VAF 22/96 reads (23%) | catalogued as COSV99878688; called by muse, mutect2, varscan2
- TTLL6 | c.1950C>T p.L650= (on ENST00000393382 / NM_001130918.3; = p.L343= on NM_173623.3) | Silent (SNP) | VAF 76/208 reads (37%) | catalogued as COSV64977105; called by muse, mutect2, varscan2
- VAV3 | c.2487A>T p.G829= | Silent (SNP) | VAF 53/286 reads (19%) | catalogued as COSV58381801; called by muse, mutect2, varscan2
- VPS13B | c.8730C>T p.P2910= | Silent (SNP) | VAF 8/74 reads (11%) | catalogued as COSV100662251, COSV62140232; called by muse, mutect2, varscan2
- VPS37A | c.1014A>T p.A338= | Silent (SNP) | VAF 29/50 reads (58%) | catalogued as COSV61364797; called by muse, mutect2, varscan2
- ZAR1 | c.1212C>T p.C404= | Silent (SNP) | VAF 15/80 reads (19%) | catalogued as rs367693998; called by muse, mutect2, varscan2
- ZEB2 | c.2106T>C p.N702= | Silent (SNP) | VAF 51/213 reads (24%) | catalogued as rs1560606563, COSV57956203; called by muse, mutect2, varscan2
- AP000769.5 | chr11:65499078 T>C | 5'Flank (SNP) | VAF 22/95 reads (23%) | catalogued as rs374669413; called by muse, mutect2, varscan2
- ELMOD2 | c.*1A>G | 3'UTR (SNP) | VAF 16/28 reads (57%) | catalogued as COSV100062742; called by muse, mutect2, varscan2
- POLH | c.*5712del | 3'UTR (DEL) | VAF 15/52 reads (29%) | called by mutect2, pindel, varscan2
- RNU7-174P | chr8:80558968 G>C | 5'Flank (SNP) | VAF 5/46 reads (11%) | called by muse, mutect2, varscan2
